TCGA case TCGA-A2-A04V — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64f67506-f2df-4f0a-b7be-29b4949e986a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 1,920 days (5.3 years).

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 39.0 years (14,250 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Lower Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment dose: 4,584 mg; Prescribed dose: 1146; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment dose: 460 mg; Prescribed dose: 115; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 107 days; Days to treatment end: 1,258 days (3.4 years); Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 1,269 days (3.5 years); Days to treatment end: 1,439 days (3.9 years); Prescribed dose: 2.5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Exemestane; Treatment intent type: Adjuvant; Days to treatment start: 1,452 days (4.0 years); Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Recurrent Disease; Days to treatment start: 1,577 days (4.3 years); Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Synchronous primary; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA.
   Recorded as not given: Pharmaceutical Therapy, NOS (Doxorubicin Hydrochloride); Pharmaceutical Therapy, NOS (Exemestane); Pharmaceutical Therapy, NOS (Letrozole); Radiation Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen).
3. Diagnosis record without a diagnosis name: Age at diagnosis: 43.0 years (15,720 days); Days to diagnosis: 1,470 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site, for progressive disease; Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (2 entries)
- Day 1,470 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,920 days (5.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Positive; Test value range: 10-19%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A04V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-A2-A04V-01A-02-BS2: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 25; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide TCGA-A2-A04V-01A-02-MS2: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A04V-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A04V-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Her2 cent17 ratio: 1.1; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Pr positivity scale other: Moderate; Er positivity scale other: Strong; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Lower Outer Quadrant; Anatomic organ subdivision: Right.
- Follow-up form: Tumor status: With tumor; New tumor event surgery: No; New tumor event surgery met: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 4.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 3.
- Drug treatment 4: Regimen number: 6.
- Drug treatment 5: Regimen number: 5; Pharmaceutical therapy drug name: Xeloda; Therapy regimen: Recurrence.
- Drug treatment 6: Regimen number: 2; Pharmaceutical therapy drug name: Adriamycin.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Infiltrating Ductal Carcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 15.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Adriamycin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,920 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,920 days; disease-free interval: event (new tumor event after initially disease-free), 1,470 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,470 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A04V-01A-21D-A036-01): tumor purity 0.84, ploidy 1.99, whole-genome doublings 0.
